FM case AD10444 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/1d7cce67-0331-4626-a7b8-a314202ac224

Female, 66.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the fallopian tube; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
